Somatic mutation profile of tumor specimen C3N-02788-03 (aliquot CPT0206350009) from CPTAC case C3N-02788, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 64.7 years (23,634 days).
Specimen C3N-02788-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd4f291f-9c9e-4183-ac9f-436d12831313.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02788-71 (Blood Derived Normal), aliquot CPT0206390002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5214d1c-e504-4ef2-bf21-42fb79f4ec6b

The open-access MAF lists 97 somatic variants for this specimen: 61 protein-altering or splice-affecting, 28 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 28, Nonsense Mutation 5, RNA 3, 3'UTR 2, Intron 2, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 373/673 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AADACL3 | c.488T>C p.V163A | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV60198922; called by muse, mutect2
- ARFGEF3 | c.6262C>T p.R2088* | Nonsense Mutation (SNP) | VAF 43/100 reads (43%) | catalogued as rs1281263362, COSV52452202, COSV52457190; called by muse, mutect2, varscan2
- ATXN1 | c.1295C>T p.T432M | Missense Mutation (SNP) | VAF 110/409 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs779131078; called by muse, mutect2, varscan2
- C8orf34 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs759635250, COSV61382468; called by muse, mutect2, varscan2
- CD163L1 | c.3253G>A p.A1085T | Missense Mutation (SNP) | VAF 177/506 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1242468551, COSV100549927; called by muse, mutect2, varscan2
- CFAP410 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 24/478 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs377552361, COSV57394180; called by muse, mutect2
- CGN | c.3398G>A p.R1133H | Missense Mutation (SNP) | VAF 87/277 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199924639, COSV54972589; called by muse, mutect2, varscan2
- CNTNAP2 | c.241C>T p.H81Y | Missense Mutation (SNP) | VAF 130/537 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV62274519; called by muse, mutect2, varscan2
- COL3A1 | c.2564G>C p.G855A | Missense Mutation (SNP) | VAF 75/232 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM1412635; called by muse, mutect2, varscan2
- CPNE8 | c.650_653del p.V217Efs*14 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as rs1426881805; called by pindel, varscan2
- DARS2 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 16/299 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs774630991, CM143074; called by muse, mutect2
- DOCK6 | c.4627C>T p.R1543W | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs751621149; called by muse, mutect2
- EGF | c.2326G>A p.D776N | Missense Mutation (SNP) | VAF 108/381 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as rs1390232915; called by muse, mutect2, varscan2
- EPHB2 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs372282301; called by muse, mutect2, varscan2
- FREM2 | c.7874G>A p.R2625H | Missense Mutation (SNP) | VAF 47/220 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs765507407, COSV54831023; called by muse, mutect2, varscan2
- GFY | c.1222G>A p.G408R | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778327967, COSV54528737; called by muse, mutect2, varscan2
- HS3ST1 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 110/274 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.761); catalogued as COSV50023300; called by muse, mutect2, varscan2
- IRX4 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as rs1476578558; called by muse, varscan2
- KIF2B | c.338C>T p.T113M | Missense Mutation (SNP) | VAF 11/242 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as rs1479427821, COSV52127121; called by muse, mutect2
- KRTAP2-3 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 223/354 reads (63%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.979); catalogued as rs772866341; called by muse, mutect2, varscan2
- LILRB2 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 132/339 reads (39%) | catalogued as rs746435174, COSV58747816; called by muse, mutect2, varscan2
- LTBP4 | c.2273G>A p.R758Q (on ENST00000308370 / NM_001042544.1; = p.R721Q on NM_003573.2) | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs574172342, COSV52583770; called by muse, mutect2, varscan2
- MUC3A | c.8918C>T p.P2973L | Missense Mutation (SNP) | VAF 55/373 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.031); catalogued as rs577819188; called by muse, mutect2, varscan2
- NECTIN4 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 155/525 reads (30%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.996); catalogued as rs1306418043; called by muse, mutect2, varscan2
- PARP1 | c.1093G>A p.V365M | Missense Mutation (SNP) | VAF 20/384 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.094); catalogued as rs774530658, COSV64690473; called by muse, mutect2
- PCDHB2 | c.2337G>T p.Q779H | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV50569850, COSV99039327; called by muse, mutect2, varscan2
- PTPRN2 | c.1693G>A p.V565M | Missense Mutation (SNP) | VAF 132/497 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as rs746331581, COSV67064337; called by muse, mutect2, varscan2
- SLC22A9 | c.1070C>T p.T357M | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs141060614; called by muse, mutect2, varscan2
- SLITRK3 | c.1446G>C p.L482F | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1274006560; called by muse, mutect2
- SMARCA2 | c.2087G>A p.R696K | Missense Mutation (SNP) | VAF 64/229 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.018); catalogued as COSV104414239; called by muse, mutect2, varscan2
- UNC13C | c.3170G>A p.R1057Q | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.96); catalogued as rs182809015, COSV52894311; called by muse, mutect2, varscan2
- VAX1 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 166/338 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs547581837, COSV53329339; called by muse, mutect2, varscan2
- WNT1 | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs745852237; called by muse, mutect2, varscan2
- ADGB | c.725A>T p.K242I | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BTBD2 | c.1160G>A p.S387N | Missense Mutation (SNP) | VAF 85/285 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.025); called by mutect2, varscan2
- ECI2 | c.867G>T p.K289N (on ENST00000380118 / NM_206836.3; = p.K259N on NM_006117.2) | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- ETF1 | c.1136C>G p.A379G | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- FAM169A | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- GHRHR | c.848G>A p.W283* | Nonsense Mutation (SNP) | VAF 200/994 reads (20%) | called by muse, mutect2, varscan2
- GLT1D1 | c.745T>A p.S249T (on ENST00000442111 / NM_001366889.1; = p.S169T on NM_144669.3) | Missense Mutation (SNP) | VAF 92/368 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GOLGA6L6 | c.1981C>G p.Q661E | Missense Mutation (SNP) | VAF 90/373 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0); called by mutect2, varscan2
- HAUS8 | c.818A>C p.Q273P | Missense Mutation (SNP) | VAF 65/230 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- HECW1 | c.745C>G p.Q249E | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IRF5 | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 27/254 reads (11%) | called by muse, mutect2, varscan2
- KDM2A | c.987C>G p.Y329* | Nonsense Mutation (SNP) | VAF 30/106 reads (28%) | called by muse, mutect2, varscan2
- LHFPL1 | c.345G>C p.M115I | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, varscan2
- LXN | c.388T>G p.S130A | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR11L1 | c.679A>G p.R227G | Missense Mutation (SNP) | VAF 14/477 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.208); called by muse, mutect2
- PHLDA3 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 20/509 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.055); called by muse, mutect2
- PPARGC1A | c.255G>T p.E85D | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- RIMBP2 | c.2960C>T p.T987I | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- SORCS3 | c.1001A>G p.E334G | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SP100 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2
- SYCP2 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.065); called by muse, varscan2
- TMPRSS11B | c.373G>A p.V125I | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- TTC6 | c.160C>T p.L54F | Missense Mutation (SNP) | VAF 27/382 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.028); called by muse, mutect2
- USH2A | c.594A>G p.I198M | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.273); called by muse, mutect2
- WDR18 | c.1163A>C p.E388A | Missense Mutation (SNP) | VAF 83/209 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- WDR74 | c.859T>C p.C287R | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF850 | c.3040T>A p.C1014S | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ADGRB3 | c.1305C>T p.S435= | Silent (SNP) | VAF 45/202 reads (22%) | catalogued as rs201961515; called by muse, mutect2, varscan2
- AGBL2 | c.2481C>T p.P827= | Silent (SNP) | VAF 43/126 reads (34%) | called by muse, mutect2, varscan2
- ALB | c.1389A>G p.K463= | Silent (SNP) | VAF 46/130 reads (35%) | called by muse, mutect2, varscan2
- BCL11B | c.729G>A p.T243= (on ENST00000357195 / NM_001282237.2; = p.T172= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/302 reads (4%) | catalogued as COSV61735876; called by muse, mutect2
- BEND3 | c.2127C>A p.P709= | Silent (SNP) | VAF 79/238 reads (33%) | called by muse, varscan2
- BEND3 | c.2061C>T p.P687= | Silent (SNP) | VAF 65/198 reads (33%) | catalogued as rs781803404; called by muse, varscan2
- CERCAM | c.1548G>A p.K516= | Silent (SNP) | VAF 31/99 reads (31%) | called by muse, mutect2, varscan2
- CETN3 | c.417T>G p.L139= | Silent (SNP) | VAF 44/138 reads (32%) | called by muse, mutect2, varscan2
- CNTNAP3 | c.2004C>T p.S668= | Silent (SNP) | VAF 170/477 reads (36%) | called by muse, mutect2, varscan2
- DAB1 | c.42C>T p.S14= | Silent (SNP) | VAF 9/143 reads (6%) | catalogued as rs749634644, COSV59724931; called by muse, mutect2
- FLG2 | c.1593T>C p.F531= | Silent (SNP) | VAF 40/364 reads (11%) | called by muse, mutect2, varscan2
- GABBR1 | c.2347C>T p.L783= | Silent (SNP) | VAF 72/236 reads (31%) | catalogued as COSV63541633; called by muse, mutect2, varscan2
- GAPDH | c.432C>T p.L144= | Silent (SNP) | VAF 99/225 reads (44%) | catalogued as rs1283284118; called by muse, mutect2, varscan2
- GFM2 | c.183C>T p.S61= | Silent (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2, varscan2
- H4C3 | c.57T>C p.H19= | Silent (SNP) | VAF 61/168 reads (36%) | called by muse, mutect2, varscan2
- HCAR3 | c.1032G>A p.A344= | Silent (SNP) | VAF 76/257 reads (30%) | catalogued as rs367719265; called by muse, mutect2, varscan2
- HCRTR1 | c.267C>T p.S89= | Silent (SNP) | VAF 129/350 reads (37%) | catalogued as COSV65485714; called by muse, mutect2, varscan2
- KCNA7 | c.399C>T p.F133= | Silent (SNP) | VAF 111/474 reads (23%) | catalogued as rs760496009, COSV55504173; called by muse, mutect2, varscan2
- MFN2 | c.180G>A p.T60= | Silent (SNP) | VAF 172/556 reads (31%) | catalogued as rs776601428; called by muse, varscan2
- NCR1 | c.60C>T p.S20= | Silent (SNP) | VAF 71/427 reads (17%) | catalogued as rs919870508; called by muse, mutect2, varscan2
- OR10A4 | c.612T>C p.T204= | Silent (SNP) | VAF 96/303 reads (32%) | catalogued as COSV65842080; called by muse, mutect2, varscan2
- PCDHA1 | c.1362G>A p.A454= | Silent (SNP) | VAF 194/711 reads (27%) | catalogued as rs782735155, COSV65372597; called by muse, mutect2, varscan2
- RGL3 | c.1785C>T p.F595= | Silent (SNP) | VAF 32/109 reads (29%) | catalogued as COSV100993093; called by muse, mutect2, varscan2
- SERPINE1 | c.501A>G p.T167= | Silent (SNP) | VAF 24/592 reads (4%) | called by muse, mutect2
- SIGLEC8 | c.585C>T p.S195= | Silent (SNP) | VAF 62/145 reads (43%) | catalogued as rs761848638, COSV58472864, COSV58473549; called by muse, mutect2, varscan2
- SLC44A2 | c.1377C>T p.F459= | Silent (SNP) | VAF 124/346 reads (36%) | catalogued as COSV59834966; called by muse, mutect2, varscan2
- SLX4 | c.2925G>T p.P975= | Silent (SNP) | VAF 65/233 reads (28%) | called by muse, mutect2, varscan2
- TMEM131L | c.4032C>T p.F1344= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as rs1253079020; called by muse, mutect2, varscan2
- ANXA2P2 | n.600C>T | RNA (SNP) | VAF 138/525 reads (26%) | called by muse, mutect2, varscan2
- COL18A1 | c.3597+9C>T | Intron (SNP) | VAF 61/210 reads (29%) | catalogued as rs756318040, COSV60593317; called by muse, varscan2
- DNM1P46 | n.386G>A | RNA (SNP) | VAF 78/333 reads (23%) | catalogued as rs771983646; called by muse, mutect2, varscan2
- LINC01804 | n.310C>T | RNA (SNP) | VAF 24/86 reads (28%) | called by muse, mutect2, varscan2
- MIPOL1 | c.*12C>T | 3'UTR (SNP) | VAF 57/148 reads (39%) | catalogued as rs550242684; called by muse, mutect2, varscan2
- PREX2 | c.3146+1327G>C | Intron (SNP) | VAF 4/22 reads (18%) | catalogued as rs1299871915; called by muse, mutect2
- RNF170 | c.*1653T>A | 3'UTR (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- SEMA3C | chr7:80922265 C>A | 5'Flank (SNP) | VAF 16/92 reads (17%) | called by muse, mutect2, varscan2
